Gene-level copy-number profile of tumor specimen HCM-CSHL-0247-C18-06A from HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16c6db05-f1fa-4c04-b67b-d16a67a32e30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0247-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/02e795b6-33b6-4d5d-a3b2-f35442af3b88

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 35; copy number 2: 16,758; copy number 3: 35; copy number 4: 31,698; copy number 5: 78; copy number 6: 8,394; copy number 7: 1; copy number 9: 27; copy number 10: 1,298; copy number 11: 14; copy number 14: 11.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,522,878–73,543,796, 3 genes (within-gene range 0–2): AC005225.3, ACOT1, NT5CP2.
- chr17:18,426,861–18,475,920, 6 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–4): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr19:43,153,279–43,269,530, 5 genes: AC005392.1, PSG5, PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,350 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,446–522,928, 14 genes, copy number 11: AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr3:89,047,442–90,030,495, 6 genes, copy number 10: GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 9–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
